Somatic mutation profile of tumor specimen TCGA-CA-5254-01A (aliquot TCGA-CA-5254-01A-21D-1835-10) from TCGA case TCGA-CA-5254, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 42.2 years (15,415 days).
Specimen TCGA-CA-5254-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9056a9fe-c9ee-4c77-96aa-6c324d22e2fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CA-5254-10A (Blood Derived Normal), aliquot TCGA-CA-5254-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/296ea04b-4e00-462f-af01-5a431133dc00

The open-access MAF lists 214 somatic variants for this specimen: 166 protein-altering or splice-affecting, 40 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 141, Silent 40, Nonsense Mutation 12, Intron 6, Frame Shift Ins 5, Frame Shift Del 4, 3'UTR 1, RNA 1, In Frame Ins 1, In Frame Del 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 16/39 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248104, COSV99031563; called by muse, mutect2, varscan2
- SERPINA1 | c.415G>A p.G139S | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.964); catalogued as rs11558261, CM900183, COSV100872063; ClinVar: pathogenic / other; called by mutect2, varscan2
- AASDH | c.139A>T p.N47Y | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as COSV99221120; called by muse, mutect2, varscan2
- ABCA13 | c.424C>T p.R142* | Nonsense Mutation (SNP) | VAF 9/35 reads (26%) | catalogued as rs369201533; called by muse, mutect2, varscan2
- ABCA2 | c.3818G>A p.R1273Q (on ENST00000614293; = p.R1243Q on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs751449038, COSV99687458; called by muse, mutect2, varscan2
- ABCB8 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV99874227; called by muse, mutect2, varscan2
- ACER1 | c.561G>A p.W187* | Nonsense Mutation (SNP) | VAF 11/25 reads (44%) | catalogued as COSV56835292; called by muse, mutect2, varscan2
- ACKR4 | c.563T>C p.F188S | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs1221481797, COSV51442384; called by muse, mutect2, varscan2
- ADAM7 | c.1385C>T p.P462L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.039); catalogued as rs765178430, COSV51537362; called by muse, mutect2, varscan2
- ADAMTS7 | c.694C>T p.R232C | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs116658641, COSV101182992; called by muse, mutect2, varscan2
- ADAT1 | c.446C>T p.P149L | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770715111, COSV100329192; called by muse, mutect2, varscan2
- AGXT2 | c.1115C>T p.A372V | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.146); catalogued as rs1289298122, COSV51487805; called by muse, mutect2, varscan2
- AMOTL1 | c.1649A>G p.N550S | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.045); catalogued as COSV100504338; called by mutect2, varscan2
- ANKAR | c.3797C>T p.S1266L | Missense Mutation (SNP) | VAF 30/133 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as rs764681188, COSV55610207; called by muse, mutect2, varscan2
- APOBEC3B | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.53); PolyPhen benign (0.012); catalogued as COSV59840850; called by muse, mutect2, varscan2
- ARAP2 | c.3761C>A p.S1254* | Nonsense Mutation (SNP) | VAF 13/54 reads (24%) | catalogued as COSV100394448; called by muse, mutect2, varscan2
- ATXN2 | c.3922C>T p.H1308Y (on ENST00000550104; = p.H1148Y on NM_002973.4) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.968); catalogued as COSV100374189; called by muse, mutect2, varscan2
- BFSP1 | c.1678C>T p.R560C | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.431); catalogued as rs147422987; called by muse, mutect2, varscan2
- BMP2 | c.124T>G p.S42A | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV101122077; called by muse, mutect2, varscan2
- BPTF | c.8045G>A p.S2682N | Missense Mutation (SNP) | VAF 15/136 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV100074691; called by muse, mutect2, varscan2
- C10orf120 | c.899A>T p.D300V | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV100271592; called by muse, mutect2, varscan2
- CC2D1A | c.2455-1G>A p.X819_splice | Splice Site (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99582836; called by mutect2, varscan2
- CCDC8 | c.1043C>A p.P348Q | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.06); catalogued as COSV100282001; called by muse, mutect2, varscan2
- CDH22 | c.1858G>A p.A620T | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs144477780; called by muse, mutect2, varscan2
- CECR2 | c.3583C>T p.R1195W (on ENST00000342247 / NM_001290047.2; = p.R1011W on NM_001290046.1) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs568030540, COSV52837917, COSV52840055; called by muse, mutect2, varscan2
- CEP112 | c.2225C>G p.S742* | Nonsense Mutation (SNP) | VAF 10/65 reads (15%) | catalogued as COSV101210694; called by muse, mutect2, varscan2
- CFAP70 | c.2010T>A p.D670E | Missense Mutation (SNP) | VAF 43/68 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV100160471; called by muse, mutect2, varscan2
- CFAP70 | c.320C>T p.A107V | Missense Mutation (SNP) | VAF 20/99 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV100160474; called by muse, mutect2, varscan2
- CLEC4C | c.82T>C p.S28P | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.795); catalogued as COSV100665424; called by muse, mutect2, varscan2
- CNOT7 | c.430G>T p.G144* | Nonsense Mutation (SNP) | VAF 40/107 reads (37%) | catalogued as COSV100778542; called by muse, mutect2, varscan2
- CNTNAP2 | c.632T>C p.V211A | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.297); catalogued as rs367652115; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPED1 | c.593G>A p.C198Y | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV100120495; called by muse, mutect2, varscan2
- CR2 | c.2897C>T p.A966V | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.891); catalogued as rs1193574112, COSV100889719, COSV65505871; called by muse, varscan2
- CSMD1 | c.5144G>A p.R1715Q (on ENST00000520002; = p.R1714Q on NM_033225.6) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs747749324, COSV59310534; called by muse, mutect2, varscan2
- CSMD3 | c.9476G>T p.G3159V (on ENST00000297405 / NM_001363185.1; = p.G2990V on NM_052900.3) | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52303518, COSV99831504; called by muse, mutect2, varscan2
- CTCF | c.778A>T p.K260* | Nonsense Mutation (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99865060; called by muse, mutect2, varscan2
- CTR9 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV100797338; called by muse, mutect2, varscan2
- DDIT4L | c.434G>T p.C145F | Missense Mutation (SNP) | VAF 30/63 reads (48%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.45); catalogued as rs1411556625, COSV99913877; called by muse, mutect2, varscan2
- DPEP3 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as rs150317704, COSV52053032; called by muse, mutect2, varscan2
- DRD5 | c.634G>A p.V212M | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.379); catalogued as rs1229920214, COSV100431706; called by muse, mutect2, varscan2
- DZIP1 | c.610G>T p.D204Y | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV61265483; called by muse, mutect2, varscan2
- EGFR | c.3016G>A p.D1006N | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as COSV99289896; called by muse, mutect2, varscan2
- EIF4H | c.232A>G p.T78A | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99733400; called by muse, mutect2
- EIF6 | c.546G>A p.V182= | Splice Region (SNP) | VAF 13/26 reads (50%) | catalogued as COSV99863771; called by muse, mutect2, varscan2
- F7 | c.1090C>T p.R364W | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs750980786, CM940394, COSV100660989, COSV60644880; called by muse, mutect2, varscan2
- FASTKD3 | c.406C>G p.R136G | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99241589; called by muse, mutect2, varscan2
- GABRA1 | c.926A>T p.Y309F | Missense Mutation (SNP) | VAF 80/149 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50102834; called by muse, mutect2, varscan2
- GBP4 | c.453C>A p.H151Q | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.96); PolyPhen benign (0.14); catalogued as COSV63254041; called by muse, mutect2, varscan2
- GPR37L1 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.589); catalogued as rs765131475, COSV66161986; called by muse, mutect2, varscan2
- GRAMD1B | c.1153G>A p.V385M | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1262409324, COSV100454601; called by muse, mutect2, varscan2
- GRK5 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as rs146569660; called by muse, mutect2, varscan2
- HDAC9 | c.1719A>T p.Q573H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.027); catalogued as COSV67772325; called by muse, mutect2, varscan2
- HOXD13 | c.724G>A p.V242M | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.119); catalogued as COSV101184232; called by muse, mutect2, varscan2
- HRNR | c.1259C>A p.S420Y | Missense Mutation (SNP) | VAF 34/64 reads (53%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.907); catalogued as rs941466916, COSV100913330; called by muse, mutect2, varscan2
- INHA | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99216672; called by muse, mutect2, varscan2
- ITGA11 | c.1330G>A p.G444R | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs755899934, COSV100241350; called by muse, mutect2, varscan2
- KAT2B | c.1560C>A p.N520K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV55428751, COSV99769145; called by muse, mutect2, varscan2
- KCMF1 | c.434C>T p.S145L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as COSV69053675; called by muse, mutect2, varscan2
- KIAA1109 | c.320G>A p.R107Q | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs1235726317, COSV52661055, COSV99149397; called by muse, mutect2, varscan2
- KPRP | c.1535A>C p.D512A | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100908690; called by muse, mutect2, varscan2
- KRT17 | c.563A>G p.N188S | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.431); catalogued as COSV100245112; called by muse, mutect2, varscan2
- L1TD1 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs534791481, COSV100776561; called by muse, mutect2, varscan2
- LEPR | c.3282G>T p.L1094F | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV62747401; called by muse, mutect2, varscan2
- LINGO1 | c.221G>A p.R74H | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs749055760, COSV100796362; called by muse, mutect2, varscan2
- LRRC7 | c.3266C>A p.P1089H (on ENST00000651989 / NM_001370785.2; = p.P1056H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV99226016; called by muse, mutect2, varscan2
- LRRIQ1 | c.419C>A p.P140H | Missense Mutation (SNP) | VAF 52/126 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.319); catalogued as COSV67813396; called by muse, mutect2, varscan2
- LRRK2 | c.3406C>A p.L1136I | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.136); catalogued as COSV100109874, COSV54167465; called by muse, varscan2
- MAP3K1 | c.1976G>C p.R659T | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV101266589; called by muse, varscan2
- MAP3K1 | c.2014G>A p.E672K | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV101266591, COSV68125050, COSV99064094; called by muse, varscan2
- MAP3K4 | c.1015A>T p.T339S | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100815264; called by muse, mutect2, varscan2
- MASP1 | c.939G>T p.E313D | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99397074; called by muse, mutect2, varscan2
- MSL2 | c.688G>A p.D230N | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.006); catalogued as rs775761294, COSV99386902; called by mutect2, varscan2
- MSS51 | c.1063C>T p.H355Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV55019134; called by muse, mutect2, varscan2
- MYRF | c.607C>T p.R203W (on ENST00000278836 / NM_001127392.3; = p.R194W on NM_013279.4) | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1165015760, COSV99606918; called by muse, mutect2, varscan2
- NEBL | c.2980G>A p.G994S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65802707, COSV65804147, COSV65806285; called by muse, mutect2, varscan2
- NEK3 | c.1153T>G p.L385V | Missense Mutation (SNP) | VAF 62/127 reads (49%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV99317548; called by muse, mutect2, varscan2
- NES | c.1176dup p.T393Hfs*39 | Frame Shift Ins (INS) | VAF 6/17 reads (35%) | catalogued as rs759081520; called by mutect2, varscan2
- NLRP9 | c.2209G>A p.V737I | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT tolerated (0.08); PolyPhen benign (0.115); catalogued as rs374061744, COSV100242939; called by muse, mutect2, varscan2
- NNT | c.2146C>T p.L716F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV99238757; called by muse, mutect2, varscan2
- NOS3 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774225083, COSV52487032; called by muse, mutect2, varscan2
- NOX4 | c.996A>T p.K332N | Missense Mutation (SNP) | VAF 31/138 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as COSV99630231; called by muse, mutect2, varscan2
- NUP50 | c.1267A>G p.N423D | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100754300; called by muse, mutect2, varscan2
- OBSCN | c.18730C>T p.P6244S | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.33); PolyPhen benign (0.023); catalogued as COSV99476540; called by muse, mutect2, varscan2
- OCRL | c.254G>A p.R85Q | Missense Mutation (SNP) | VAF 28/34 reads (82%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs1055113235, COSV63981583; called by muse, mutect2, varscan2
- OR12D2 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.011); catalogued as COSV101011216; called by muse, mutect2, varscan2
- OR1L8 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100508506; called by muse, mutect2, varscan2
- OR2Y1 | c.488C>G p.A163G | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV57136556; called by muse, mutect2, varscan2
- PAX2 | c.743G>A p.R248Q (on ENST00000428433 / NM_003987.5; = p.R225Q on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs765955789, COSV62291074; called by muse, mutect2, varscan2
- PCDH11X | c.3784C>T p.P1262S | Missense Mutation (SNP) | VAF 140/200 reads (70%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.61); catalogued as COSV100010992; called by muse, mutect2, varscan2
- PCDH18 | c.3389A>C p.Q1130P | Missense Mutation (SNP) | VAF 39/71 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100787240; called by muse, mutect2, varscan2
- PCDH9 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV100119809; called by muse, mutect2, varscan2
- PCDHA12 | c.2300C>T p.T767M | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.046); catalogued as rs372461540, COSV56496988; called by muse, mutect2, varscan2
- PCDHA5 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.226); catalogued as rs1554129201, COSV100972227; called by muse, mutect2, varscan2
- PCDHGA12 | c.1837G>A p.E613K | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.941); catalogued as COSV99339493; called by muse, mutect2, varscan2
- PCSK1 | c.923G>A p.G308E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs990328651, COSV60735780; called by muse, mutect2, varscan2
- PEX13 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.964); catalogued as COSV99692776; called by muse, varscan2
- PGR | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 18/27 reads (67%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.007); catalogued as COSV54796267; called by muse, mutect2, varscan2
- PKHD1 | c.5856A>T p.Q1952H | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.011); catalogued as rs985097693, COSV100582590; called by muse, mutect2, varscan2
- PLCH1 | c.1048G>A p.G350S (on ENST00000340059 / NM_001130960.2; = p.G362S on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58197761; called by muse, mutect2, varscan2
- PLEC | c.8728G>A p.A2910T (on ENST00000322810 / NM_201380.4; = p.A2800T on NM_000445.5) | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs200683827; ClinVar: uncertain significance; called by muse, varscan2
- PNMA8B | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV100885389; called by muse, mutect2, varscan2
- PNPLA5 | c.1216G>A p.V406I | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.035); catalogued as rs751134085, COSV53374145; called by muse, varscan2
- PPFIA3 | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.061); catalogued as COSV100494848; called by muse, mutect2, varscan2
- PPIAL4G | c.230C>T p.S77F | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.988); catalogued as COSV101343998; called by muse, mutect2, varscan2
- PRKCG | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 17/90 reads (19%) | catalogued as rs750289253, COSV99668868; called by muse, mutect2, varscan2
- PRLR | c.1745C>T p.S582L | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV99184312; called by muse, mutect2, varscan2
- PROZ | c.802G>T p.E268* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100720313; called by muse, mutect2, varscan2
- PTPRS | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.105); catalogued as rs200771602, COSV53637901; called by muse, mutect2, varscan2
- PTPRT | c.4241G>A p.R1414H | Missense Mutation (SNP) | VAF 44/99 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778726076, COSV61980595, COSV62037476; called by muse, mutect2, varscan2
- RESF1 | c.2564A>G p.N855S | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.87); PolyPhen benign (0.001); catalogued as rs1028854599, COSV57023792; called by muse, mutect2, varscan2
- RFT1 | c.1180G>T p.A394S | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV99965427; called by muse, mutect2, varscan2
- RHOBTB2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 6/17 reads (35%) | catalogued as rs772023790, COSV99310885; called by muse, varscan2
- RIPOR2 | c.1309C>A p.P437T | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.281); catalogued as COSV99428969; called by muse, mutect2, varscan2
- RNPEPL1 | c.1423T>C p.F475L | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV99549441; called by muse, varscan2
- ROBO2 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778684665, COSV59899211; called by muse, mutect2, varscan2
- RP1L1 | c.1598C>T p.S533L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.072); catalogued as rs751415374, COSV66757419; called by muse, mutect2
- RPL10L | c.70C>T p.R24* | Nonsense Mutation (SNP) | VAF 6/33 reads (18%) | catalogued as rs141953926, COSV53559245; called by muse, varscan2
- RSPO4 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs369687640; called by muse, mutect2, varscan2
- SCN4A | c.4240G>A p.V1414I | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs369929462; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SH3BP5 | c.214A>C p.K72Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.882); catalogued as COSV99508208; called by muse, mutect2, varscan2
- SMG7 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 50/89 reads (56%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.865); catalogued as rs748371837, COSV100750194; called by muse, mutect2, varscan2
- SPATA31D1 | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as COSV61195211, COSV61196298; called by muse, mutect2, varscan2
- SPATA31D1 | c.4543C>A p.P1515T | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.047); catalogued as rs1191565996, COSV100782779, COSV61195218; called by muse, mutect2, varscan2
- SPOCK3 | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.17); PolyPhen benign (0.015); catalogued as rs767498297, COSV100692841; called by muse, mutect2, varscan2
- STAC2 | c.1134C>G p.I378M | Missense Mutation (SNP) | VAF 55/87 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV61065403; called by muse, mutect2, varscan2
- STOX2 | c.905C>T p.T302M | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.001); catalogued as rs369084419; called by muse, mutect2, varscan2
- SVEP1 | c.5626G>A p.G1876R | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99928827; called by muse, mutect2
- TBC1D10C | c.268C>T p.R90W | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141022722; called by muse, mutect2, varscan2
- TBX4 | c.729C>A p.N243K | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99540117; called by muse, mutect2, varscan2
- TKFC | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs759141199, COSV99582374; called by muse, mutect2, varscan2
- TNKS2 | c.659G>C p.G220A | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV100861053; called by muse, mutect2, varscan2
- TOGARAM2 | c.345C>G p.N115K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.057); catalogued as COSV101091050; called by muse, mutect2, varscan2
- TPR | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.498); catalogued as COSV66601063; called by muse, mutect2, varscan2
- TRAPPC2L | c.133G>A p.A45T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.59); PolyPhen benign (0.013); catalogued as rs1272548985, COSV51935603; called by muse, mutect2, varscan2
- TRPS1 | c.1630G>T p.G544W (on ENST00000220888 / NM_001330599.2; = p.G557W on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as COSV99629947; called by muse, mutect2, varscan2
- TTC29 | c.777A>C p.K259N | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57274632; called by muse, mutect2, varscan2
- TTC32 | c.323T>G p.F108C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61267619; called by muse, mutect2, varscan2
- TTC7A | c.2073G>T p.E691D | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.955); catalogued as COSV99766310; called by muse, mutect2, varscan2
- TTLL5 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.189); catalogued as COSV100089865; called by muse, mutect2, varscan2
- TTLL9 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 12/61 reads (20%) | catalogued as rs773203476, COSV60589706; called by muse, mutect2, varscan2
- TTN | c.93604T>C p.W31202R (on ENST00000591111; = p.W23778R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/42 reads (24%) | PolyPhen probably damaging (0.999); catalogued as COSV100606267; called by muse, mutect2, varscan2
- UNC5B | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs1340655582, COSV100100624; called by muse, mutect2, varscan2
- UROS | c.793T>C p.C265R | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.202); catalogued as COSV100909678; called by muse, mutect2, varscan2
- VWF | c.5197C>A p.L1733M | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.815); catalogued as COSV99778761; called by muse, mutect2, varscan2
- WNK1 | c.4823C>T p.A1608V (on ENST00000315939 / NM_018979.4; = p.A1361V on NM_014823.3) | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.001); catalogued as rs781667314, COSV60032061; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XAB2 | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs201040075, COSV100222023; called by muse, mutect2, varscan2
- ZFHX4 | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 61/291 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV99261437; called by muse, mutect2, varscan2
- ZFHX4 | c.4625A>C p.K1542T | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV99261438; called by muse, mutect2, varscan2
- ZIC1 | c.943C>T p.R315C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51553293; called by muse, mutect2, varscan2
- ZNF223 | c.608T>G p.L203R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV101462622; called by muse, mutect2
- ZNF391 | c.463C>T p.H155Y | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55124919; called by muse, mutect2, varscan2
- ZNF528 | c.452T>A p.I151N | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0.145); catalogued as COSV64619462; called by muse, mutect2, varscan2
- ZSWIM2 | c.440G>A p.C147Y | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99720104; called by muse, varscan2
- ARID1A | c.4724del p.P1575Hfs*37 | Frame Shift Del (DEL) | VAF 27/88 reads (31%) | called by mutect2, pindel, varscan2
- ARMCX1 | c.555_559dup p.V187Gfs*18 | Frame Shift Ins (INS) | VAF 15/46 reads (33%) | called by mutect2, varscan2
- BRD7 | c.1413dup p.H472Afs*14 | Frame Shift Ins (INS) | VAF 16/56 reads (29%) | called by mutect2, pindel, varscan2
- CD2 | c.361del p.I121Yfs*4 | Frame Shift Del (DEL) | VAF 50/135 reads (37%) | called by mutect2, pindel, varscan2
- DISP3 | c.1103del p.L368Rfs*5 | Frame Shift Del (DEL) | VAF 3/19 reads (16%) | called by pindel, varscan2
- GP2 | c.669G>T p.L223F (on ENST00000381362 / NM_001007240.3; = p.L220F on NM_001502.4) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- NACC2 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCOA3 | c.858dup p.S287Ifs*8 | Frame Shift Ins (INS) | VAF 18/110 reads (16%) | called by mutect2, pindel, varscan2
- NQO1 | c.311_313dup p.L104dup | In Frame Ins (INS) | VAF 4/30 reads (13%) | called by mutect2, pindel
- RNF43 | c.95dup p.A33Gfs*7 | Frame Shift Ins (INS) | VAF 4/6 reads (67%) | called by mutect2, varscan2
- SEC22B | c.4G>C p.V2L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLL1 | c.1173del p.F391Lfs*19 | Frame Shift Del (DEL) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- ZACN | c.259_267del p.L87_L89del | In Frame Del (DEL) | VAF 6/18 reads (33%) | called by mutect2, varscan2
- ADGRG3 | c.1308C>T p.H436= | Silent (SNP) | VAF 39/97 reads (40%) | catalogued as rs756811215, COSV59651872; called by muse, mutect2, varscan2
- ARHGAP6 | c.69G>A p.S23= | Silent (SNP) | VAF 24/27 reads (89%) | catalogued as rs779665222, COSV100497783; called by muse, mutect2, varscan2
- CCDC102B | c.1125A>G p.G375= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV100103139; called by muse, mutect2, varscan2
- CDC20B | c.1152C>T p.H384= | Silent (SNP) | VAF 16/69 reads (23%) | catalogued as rs763435648, COSV99696777; called by muse, mutect2, varscan2
- CDH23 | c.7848C>T p.N2616= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as rs951916941, COSV56474741; called by muse, mutect2, varscan2
- CDH6 | c.2082C>T p.P694= | Silent (SNP) | VAF 5/42 reads (12%) | catalogued as rs764269155, COSV54078647, COSV99420279; called by mutect2, varscan2
- CEP135 | c.1992A>T p.T664= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV57261028, COSV99954329; called by muse, mutect2, varscan2
- CPS1 | c.1179C>A p.S393= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV99242742; called by muse, mutect2, varscan2
- DIDO1 | c.4524G>A p.G1508= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as rs928310860, COSV99825518; called by muse, mutect2, varscan2
- DIDO1 | c.1803C>T p.S601= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs370531620; called by mutect2, varscan2
- DNAH9 | c.12633C>T p.D4211= | Silent (SNP) | VAF 18/41 reads (44%) | catalogued as rs200349675, COSV52340958; called by muse, mutect2, varscan2
- EN1 | c.960G>A p.A320= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs904460049, COSV54630969; called by muse, varscan2
- EPHB1 | c.2616G>A p.A872= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as rs760099232, COSV67659427; called by muse, mutect2, varscan2
- FAM71C | c.105C>T p.G35= | Silent (SNP) | VAF 12/68 reads (18%) | catalogued as COSV100175625, COSV60943797; called by muse, mutect2, varscan2
- HECTD4 | c.5932C>A p.R1978= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV66391158, COSV66396052; called by muse, mutect2, varscan2
- ICE2 | c.2886T>C p.S962= | Silent (SNP) | VAF 31/139 reads (22%) | catalogued as COSV99831462; called by muse, mutect2, varscan2
- IGKV3D-20 | c.57C>T p.T19= | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs766150364; called by muse, mutect2, varscan2
- KALRN | c.2133G>A p.A711= | Silent (SNP) | VAF 8/28 reads (29%) | catalogued as rs771916960, COSV53760606; called by muse, mutect2, varscan2
- LRP2 | c.8847G>A p.S2949= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs181346149; ClinVar: likely benign; called by muse, mutect2, varscan2
- MED4 | c.591C>T p.G197= | Silent (SNP) | VAF 22/76 reads (29%) | catalogued as rs778728423, COSV51639158; called by muse, mutect2, varscan2
- MEFV | c.390C>T p.N130= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs780976880, COSV54826627, COSV54829656; called by muse, varscan2
- MSC | c.99C>T p.G33= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs756904680, COSV100335654; called by muse, mutect2, varscan2
- MTUS2 | c.561C>T p.V187= | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as rs771137363, COSV70923940; called by muse, mutect2, varscan2
- NBEA | c.7728G>A p.P2576= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs372021254; called by muse, mutect2, varscan2
- NCAM1 | c.1794C>T p.S598= (on ENST00000316851 / NM_181351.5; = p.S588= on NM_000615.7) | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs199567425; called by muse, mutect2, varscan2
- NEBL | c.2406C>T p.D802= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as rs748203517, COSV65802713; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP4 | c.876G>A p.T292= | Silent (SNP) | VAF 18/65 reads (28%) | catalogued as rs368289644, COSV100016064; called by muse, mutect2, varscan2
- NPTX2 | c.1143C>T p.R381= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs776156518, COSV55716965; called by mutect2, varscan2
- PCDHA11 | c.1809C>T p.N603= | Silent (SNP) | VAF 64/120 reads (53%) | catalogued as rs1554164817, COSV56518234; called by muse, mutect2, varscan2
- PCDHB4 | c.1560C>T p.Y520= | Silent (SNP) | VAF 43/94 reads (46%) | catalogued as COSV52021206; called by muse, mutect2, varscan2
- PCYOX1L | c.1029G>A p.S343= | Silent (SNP) | VAF 19/33 reads (58%) | catalogued as rs780739338, COSV99199176; called by muse, mutect2, varscan2
- PRMT6 | c.963G>A p.A321= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as COSV100791172; called by muse, mutect2, varscan2
- RBM27 | c.1434T>A p.P478= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99506030; called by muse, mutect2, varscan2
- RPS6KA4 | c.1077C>T p.Y359= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as COSV99589947; called by muse, mutect2, varscan2
- SALL3 | c.108C>T p.D36= | Silent (SNP) | VAF 10/13 reads (77%) | catalogued as rs766415840, COSV101609981; called by muse, mutect2, varscan2
- SLC22A14 | c.1686G>T p.T562= | Silent (SNP) | VAF 13/45 reads (29%) | catalogued as COSV56197770, COSV99828198; called by muse, mutect2, varscan2
- SLC6A5 | c.2298C>T p.R766= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as rs534286800, COSV54224695, COSV54226610; called by muse, mutect2, varscan2
- TMEM131L | c.4392C>T p.N1464= | Silent (SNP) | VAF 8/36 reads (22%) | catalogued as rs375228294; called by muse, mutect2, varscan2
- UNC13C | c.3408C>T p.H1136= | Silent (SNP) | VAF 28/52 reads (54%) | catalogued as rs374302903; called by muse, mutect2, varscan2
- ZNF653 | c.1383C>T p.D461= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as rs773032484, COSV99542086; called by muse, mutect2, varscan2
- CDC42BPA | c.2944-3940G>A | Intron (SNP) | VAF 17/44 reads (39%) | catalogued as rs1469275591, COSV62004015; called by muse, varscan2
- GUK1 | c.-3+366G>A | Intron (SNP) | VAF 8/23 reads (35%) | called by muse, mutect2, varscan2
- LRRFIP1 | c.250-9079C>T | Intron (SNP) | VAF 7/21 reads (33%) | catalogued as COSV99790657; called by muse, mutect2, varscan2
- MIR323A | n.49C>T | RNA (SNP) | VAF 36/81 reads (44%) | catalogued as rs775517920; called by muse, mutect2, varscan2
- NFASC | c.2470+2080C>T | Intron (SNP) | VAF 29/60 reads (48%) | catalogued as COSV100363529; called by muse, mutect2, varscan2
- PCCA | c.1285-1394A>G | Intron (SNP) | VAF 26/110 reads (24%) | called by muse, mutect2, varscan2
- PYHIN1 | c.*17C>A | 3'UTR (SNP) | VAF 81/149 reads (54%) | catalogued as rs1331933383, COSV100932569; called by muse, mutect2, varscan2
- RNF216 | c.202-132C>G | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as COSV66290260; called by muse, mutect2, varscan2
